Somatic mutation profile of tumor specimen TCGA-FW-A3I3-06A (aliquot TCGA-FW-A3I3-06A-11D-A21A-08) from TCGA case TCGA-FW-A3I3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 59.5 years (21,731 days).
Specimen TCGA-FW-A3I3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d553bf46-8e83-4247-8e73-32dddda84e68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FW-A3I3-10A (Blood Derived Normal), aliquot TCGA-FW-A3I3-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ddf9aa0-80b7-4182-adee-68f7ffe463bf

The open-access MAF lists 64 somatic variants for this specimen: 42 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 21, Nonsense Mutation 5, Frame Shift Del 4, Translation Start Site 1, Intron 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as COSV59866691; called by muse, mutect2
- ACOT4 | c.344A>G p.E115G | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV58335802; called by muse, mutect2, varscan2
- AKAP13 | c.2567T>G p.L856R | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV63461559; called by muse, mutect2, varscan2
- ALDH1B1 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 98/412 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66619367, COSV66620102; called by muse, mutect2, varscan2
- AP3B2 | c.1432C>G p.P478A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.66); catalogued as COSV55610665; called by muse, mutect2, varscan2
- CDH10 | c.443T>A p.I148N | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52574372; called by muse, mutect2, varscan2
- COL4A1 | c.1664C>A p.P555Q | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0.01); catalogued as COSV65426765; called by muse, mutect2
- CSNK1G1 | c.692G>C p.R231T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100274386, COSV57310766; called by muse, mutect2, varscan2
- DDX4 | c.1388T>A p.L463* | Nonsense Mutation (SNP) | VAF 30/316 reads (9%) | catalogued as COSV61755580; called by muse, mutect2
- DNAH9 | c.12434del p.S4145Ffs*44 | Frame Shift Del (DEL) | VAF 61/203 reads (30%) | catalogued as COSV52376984; called by mutect2, pindel, varscan2
- DPY19L1 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60582874; called by muse, mutect2, varscan2
- ELAPOR1 | c.1580C>T p.T527M | Missense Mutation (SNP) | VAF 148/177 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs41279692, COSV64040640; called by muse, mutect2, varscan2
- FAM135B | c.1933A>C p.S645R | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.235); catalogued as rs756192058, COSV52714592; called by muse, mutect2, varscan2
- FANCA | c.3931_3932del p.S1311* | Frame Shift Del (DEL) | VAF 57/262 reads (22%) | catalogued as rs1403231932; called by pindel, varscan2
- FAP | c.1127A>G p.H376R | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV51863072; called by muse, mutect2, varscan2
- FBXL7 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.31); catalogued as rs1384577870, COSV100309042, COSV61647922; called by muse, mutect2, varscan2
- FBXO38 | c.3334C>T p.R1112* (on ENST00000340253 / NM_205836.3; = p.R1037* on NM_030793.5) | Nonsense Mutation (SNP) | VAF 67/221 reads (30%) | catalogued as rs761655990, COSV57028828; called by muse, mutect2, varscan2
- GALC | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 83/141 reads (59%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV54326790; called by muse, mutect2, varscan2
- GEM | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52597829, COSV52598976; called by muse, mutect2, varscan2
- GPR65 | c.527T>A p.L176* | Nonsense Mutation (SNP) | VAF 52/179 reads (29%) | catalogued as COSV50863085; called by muse, mutect2, varscan2
- IFNA16 | c.239T>A p.F80Y | Missense Mutation (SNP) | VAF 124/143 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV66510280; called by muse, mutect2, varscan2
- IGFN1 | c.3269C>T p.A1090V (on ENST00000295591 / NM_001367841.1; = p.A3547V on NM_001164586.2) | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55175311; called by muse, mutect2, varscan2
- LGALS12 | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV55370711; called by muse, mutect2
- LRRC45 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs753739520, COSV60711814; called by muse, mutect2, varscan2
- MROH5 | c.3040C>T p.R1014C | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs754182427, COSV71300552; called by muse, mutect2, varscan2
- MSR1 | c.808T>A p.L270I | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as COSV50515445; called by muse, mutect2, varscan2
- NSA2 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 127/292 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV57188291; called by muse, mutect2, varscan2
- PACS1 | c.805+1G>A p.X269_splice | Splice Site (SNP) | VAF 7/58 reads (12%) | catalogued as COSV57698259; called by muse, mutect2, varscan2
- PRG4 | c.3136C>T p.P1046S | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV63355813; called by muse, mutect2, varscan2
- SGCA | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56248905, COSV56249726, COSV56250322; called by muse, mutect2, varscan2
- SI | c.3904G>T p.G1302* | Nonsense Mutation (SNP) | VAF 35/71 reads (49%) | catalogued as COSV100014548, COSV52284296; called by muse, mutect2, varscan2
- SLC7A2 | c.559T>C p.S187P (on ENST00000494857 / NM_001370338.1; = p.S227P on NM_003046.6) | Missense Mutation (SNP) | VAF 85/263 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774171827, COSV50256717; called by muse, mutect2, varscan2
- SLC9A7 | c.2048C>T p.T683M | Missense Mutation (SNP) | VAF 46/49 reads (94%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs146808441, COSV60381113; called by muse, mutect2, varscan2
- STAMBP | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs775741034, COSV59897648; called by muse, mutect2, varscan2
- TULP2 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 27/137 reads (20%) | catalogued as COSV55478657; called by muse, mutect2, varscan2
- WDFY3 | c.7682A>G p.H2561R | Missense Mutation (SNP) | VAF 81/147 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55704329; called by muse, mutect2, varscan2
- ZBTB43 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs752784579, COSV65094932; called by muse, mutect2, varscan2
- ZNF71 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs139335499; called by muse, mutect2, varscan2
- AATF | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- NF1 | c.2093del p.P698Lfs*50 | Frame Shift Del (DEL) | VAF 93/165 reads (56%) | called by mutect2, pindel, varscan2
- PTEN | c.491dup p.V166Sfs*14 | Frame Shift Ins (INS) | VAF 38/57 reads (67%) | called by mutect2, pindel, varscan2
- ZCCHC14 | c.1937_1940del p.P646Lfs*17 (on ENST00000268616; = p.P783Lfs*17 on NM_015144.3) | Frame Shift Del (DEL) | VAF 78/373 reads (21%) | called by mutect2, pindel, varscan2
- ACAP2 | c.225C>T p.V75= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs769640698, COSV58752858; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1296T>C p.R432= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV55001477; called by muse, mutect2, varscan2
- ARRDC2 | c.501G>A p.A167= | Silent (SNP) | VAF 62/281 reads (22%) | catalogued as rs549541387, COSV55844847, COSV55846111; called by muse, mutect2, varscan2
- BCL11A | c.1101C>T p.G367= (on ENST00000335712 / NM_001365609.1; = p.G401= on NM_018014.4) | Silent (SNP) | VAF 163/317 reads (51%) | catalogued as COSV59632641; called by muse, mutect2, varscan2
- CASP8AP2 | c.5505G>A p.K1835= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV52747944, COSV52748486; called by muse, mutect2, varscan2
- COL5A1 | c.1899C>T p.D633= | Silent (SNP) | VAF 89/104 reads (86%) | catalogued as rs757951119, COSV65670507; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOCK2 | c.735C>T p.Y245= | Silent (SNP) | VAF 80/316 reads (25%) | catalogued as rs374307327; called by muse, mutect2, varscan2
- EGFLAM | c.1107C>T p.C369= | Silent (SNP) | VAF 38/133 reads (29%) | catalogued as COSV59306259; called by muse, mutect2, varscan2
- ELAVL2 | c.501T>C p.G167= | Silent (SNP) | VAF 7/163 reads (4%) | catalogued as COSV56356733; called by muse, mutect2
- FAT4 | c.5721A>G p.E1907= | Silent (SNP) | VAF 61/99 reads (62%) | catalogued as rs145529167, COSV58691458; called by muse, mutect2, varscan2
- GRM6 | c.1857G>C p.S619= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs140658210, COSV51442043, COSV99179538; called by muse, mutect2, varscan2
- H2BC18 | c.138G>C p.L46= | Silent (SNP) | VAF 349/877 reads (40%) | catalogued as rs1427729574, COSV100516137, COSV58944457; called by muse, mutect2, varscan2
- LAMP5 | c.339C>G p.R113= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV55716759; called by muse, mutect2, varscan2
- LCP1 | c.1068C>T p.V356= | Silent (SNP) | VAF 77/149 reads (52%) | catalogued as rs1046014224, COSV59941601; called by muse, mutect2, varscan2
- MATN4 | c.399G>A p.P133= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1213455579, COSV59214146; called by muse, mutect2, varscan2
- NFATC4 | c.1098A>G p.G366= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV51605049; called by muse, mutect2, varscan2
- SCN1A | c.3015T>C p.D1005= (on ENST00000303395 / NM_001202435.3; = p.D994= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV57674430; called by muse, mutect2, varscan2
- SLC16A12 | c.813G>A p.L271= | Silent (SNP) | VAF 41/50 reads (82%) | catalogued as COSV57951111; called by muse, mutect2, varscan2
- TEX2 | c.1347C>T p.L449= | Silent (SNP) | VAF 71/334 reads (21%) | catalogued as COSV51982454; called by muse, mutect2, varscan2
- TPK1 | c.483G>A p.L161= | Silent (SNP) | VAF 144/322 reads (45%) | catalogued as COSV63642465; called by muse, mutect2, varscan2
- USP32 | c.3237C>T p.V1079= | Silent (SNP) | VAF 17/211 reads (8%) | catalogued as COSV100341789; called by muse, mutect2, varscan2
- FBXL13 | c.496-5558C>T | Intron (SNP) | VAF 20/85 reads (24%) | catalogued as rs370049398; called by muse, mutect2, varscan2
